Somatic mutation profile of tumor specimen 0DVF8W from CCDI case PBCKNY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.8 years (1,738 days).
Specimen 0DVF8W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b44c3d80-b2ab-49b7-9095-02ed424933a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVF8P (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7b1ca7f-03dd-4305-8415-8692a6d23422

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, 3'UTR 1, 3'Flank 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF1 | c.59G>A p.S20N | Missense Mutation (SNP) | VAF 26/456 reads (6%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs1048893050, COSV58228256; called by muse, mutect2
- CCDC40 | c.2309C>T p.A770V | Missense Mutation (SNP) | VAF 119/505 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749795585, COSV100884351; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNKSR2 | c.2393C>T p.A798V | Missense Mutation (SNP) | VAF 187/423 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs141899187, COSV54270440; called by muse, mutect2, varscan2
- EDRF1 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 124/515 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.046); catalogued as rs372780079; called by muse, mutect2, varscan2
- OR14J1 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 65/392 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.544); catalogued as rs1325895366, COSV65845729; called by muse, mutect2, varscan2
- TSPEAR | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 26/454 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100555875; called by muse, mutect2
- UHRF1 | c.971G>A p.R324Q (on ENST00000612630 / NM_001290050.1; = p.R337Q on NM_013282.4) | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs1203961237; called by muse, mutect2, varscan2
- ZNF268 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 268/647 reads (41%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.092); catalogued as rs781577602, COSV57212380; called by muse, mutect2, varscan2
- ZNF442 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 96/371 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.018); catalogued as rs371108711; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 40/1103 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- PARD6B | c.383del p.K128Sfs*4 | Frame Shift Del (DEL) | VAF 148/558 reads (27%) | called by mutect2, varscan2
- SPIDR | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 237/616 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- SUPV3L1 | c.1745A>G p.K582R | Missense Mutation (SNP) | VAF 83/629 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- THADA | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 31/1058 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, mutect2
- ASPHD2 | c.213C>T p.F71= | Silent (SNP) | VAF 18/246 reads (7%) | catalogued as rs749565197, COSV53218297; called by muse, mutect2
- DGAT2L6 | c.813C>T p.R271= | Silent (SNP) | VAF 184/986 reads (19%) | catalogued as rs746570087, COSV100284169; called by muse, mutect2, varscan2
- MED26 | c.534C>T p.S178= | Silent (SNP) | VAF 66/132 reads (50%) | catalogued as rs146319284; called by muse, mutect2, varscan2
- P3H2 | c.1128G>A p.K376= | Silent (SNP) | VAF 341/857 reads (40%) | called by muse, mutect2, varscan2
- VANGL2 | c.642C>T p.G214= | Silent (SNP) | VAF 177/444 reads (40%) | catalogued as rs571447557; called by muse, mutect2, varscan2
- EHD2 | c.915+25C>T | Intron (SNP) | VAF 142/285 reads (50%) | called by muse, mutect2, varscan2
- MBD1 | chr18:50267554 A>G | 3'Flank (SNP) | VAF 37/172 reads (22%) | called by muse, mutect2, varscan2
- RHD | c.*59_*77del | 3'UTR (DEL) | VAF 230/511 reads (45%) | called by mutect2, varscan2
